Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A20I, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A20I-06A (Metastatic).

[page 1 of 2]
N/A
N/A
N/A
N/A
N/A N/A N/A

DOB/Age/Sex: years Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY MACROSCOPIC DESCRIPTION

Additional block key:

2B-2D: Remainder of specimen embedded.

ICD-0-3

Melanoma, Nos 8720/3

Site: skin, thigh C44.7 lu 3/30/11

SUPPLEMENTARY REPORT

The remainder of specimen 2 has been submitted for histological examination and largely consists of skin and subcutis. A small amount of residual melanoma is seen. No lymph node tissue is identified.

The diagnosis from the original report is unchanged.

SUPPLEMENTARY SUMMARY

1. SKIN EXCISION, RIGHT MEDIAL THIGH: **Metastatic melanoma.**

/

2. SKIN EXCISION, RIGHT GROIN: **Metastatic melanoma.**

/

3. SKIN EXCISION, RIGHT LATERAL THIGH: **Metastatic melanoma.**

REPORTED BY: Dr

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

(R) medial thigh (R) groin (R) lateral thigh
Metastatic melanoma.

FROZEN SECTION REPORT

Fresh tissue was taken for the melanoma tumour banking from specimens one and two

(Registrar/ Pathologis.

MACROSCOPIC DESCRIPTION

(Dr

Three specimens were received.

1. "R MEDIAL THIGH". An excision of skin 15 x 5mm with subcutis 25 x 20 x 15mm inked blue. Half of nodule (20mm diameter) for tumour banking remainder divided into three sections and all embedded in one block.

2. "R GROIN". Excision of skin and subcutis 28 x 15 x 15mm with a subcutaneous nodule 15mm diameter. Half for tumour banking. One full face embedded in block A.

Printed:

[page 2 of 2]
Requested by: _____

MRN/Na. _____

Location: _____

Accession: _____

HISTOPATHOLOGY REPORT

3. "R LATERAL THIGH". An excision of skin 23 x 13 x 5mm with an irregular skin thickening measuring 10 x 5mm which appears to come close to one transverse margin. This overlies a region of brown discolouration within the subcutis, which is irregular, measuring approximately 6 x 4mm. Three transverse sections demonstrating all of lesion embedded in one block and remainder excluded.

MICROSCOPIC REPORT

1. "R MEDIAL THIGH".

Microscopy of skin shows a deposit of malignant epithelioid and spindle cell tumour with a morphology consistent with melanoma. The tumour is located within the dermis and superficial subcutis. A junctional component is not identified and the appearance would be consistent with a metastasis.

The deep margin is clear by 0.4mm and the closest peripheral margin is clear by 1.5mm.

2. "R GROIN".

The specimen consists of skin to a level of fascia. Microscopy a deposit of partially necrotic pigmented malignant epithelioid and spindle cell tumour with a morphology consistent with melanoma. The tumour is located within the subcutaneous tissue extending to the level of fascia. No associated lymph node tissue is identified to suggest a lymph node metastasis (additional tumour will be sampled as a supplementary report will be issued if lymph node tissue is seen). A junctional component is not identified and the appearance would be consistent with a metastasis.

The deep margin is clear by 2.7mm and the closest peripheral margin is clear by 2.5mm.

3. "R LATERAL THIGH"

Microscopy of skin shows a deposit of partially necrotic malignant epithelioid and spindle cell tumour with a morphology consistent with melanoma. The tumour is located within the dermis and superficial subcutis. A junctional component is not identified and the appearance would be consistent with a metastasis.

The deep margin is clear by 0.7mm and the closest peripheral margin is clear by 1.1mm.

SUMMARY

1. SKIN EXCISION, RIGHT MEDIAL THIGH: **Metastatic melanoma.**

2. SKIN EXCISION, RIGHT GROIN: **Metastatic melanoma.**

3. SKIN EXCISION, RIGHT LATERAL THIGH: **Metastatic melanoma.**

REPORTED BY: Dr _____

Source: NCI Genomic Data Commons file 815eaacf-0ad5-4136-bd47-b760b3b87670 (TCGA-EE-A20I.48024609-C417-41FE-B196-F319483FCE14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).